ALCHEMIST case ALCH-ADTB — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/69fc27e1-7744-494b-93d9-bb8d15877b7d

Demographics
Sex at birth: male.

Diagnoses (1)
1. Large cell neuroendocrine carcinoma: Age at diagnosis: 77.5 years (28,316 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-ADTB-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-ADTB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-ADTB-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 15; Percent necrosis: 10; Percent stromal cells: 25; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
